Somatic mutation profile of tumor specimen ALCH-ADMS-TTP1-A (aliquot ALCH-ADMS-TTP1-A-1-0-D-A565-36) from ALCHEMIST case ALCH-ADMS, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 66.2 years (24,183 days).
Specimen ALCH-ADMS-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) beb2c8cb-48eb-4c64-a1b2-7782b5d24f14.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ADMS-NB1-A (Blood Derived Normal), aliquot ALCH-ADMS-NB1-A-1-0-D-A565-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e82bc730-e1a5-40c7-a81e-dae2b86530c5

The open-access MAF lists 271 somatic variants for this specimen: 187 protein-altering or splice-affecting, 56 silent, 28 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 162, Silent 56, Intron 12, Nonsense Mutation 11, RNA 5, 5'UTR 5, Frame Shift Del 5, Splice Site 3, 5'Flank 3, Splice Region 3, 3'UTR 3, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.473G>T p.R158L | Missense Mutation (SNP) | VAF 29/183 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs587782144, CM102353, CM165595, CM994513, COSV52676395, COSV52678258, COSV52680378, COSV53545833; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAMTS19 | c.1096C>A p.L366I | Missense Mutation (SNP) | VAF 43/456 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV50764970; called by muse, mutect2
- ADGRV1 | c.8351T>C p.V2784A | Missense Mutation (SNP) | VAF 28/382 reads (7%) | SIFT tolerated (0.67); PolyPhen benign (0.04); catalogued as rs1230063727; called by muse, mutect2
- AKAP6 | c.4760G>A p.S1587N | Missense Mutation (SNP) | VAF 22/272 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs1334923209; called by muse, mutect2
- AKR7A2 | c.11C>T p.A4V | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs982673539; called by mutect2, varscan2
- AP4E1 | c.2335A>G p.T779A | Missense Mutation (SNP) | VAF 34/304 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs145037780; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APLNR | c.806C>T p.T269M | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs140178173; called by muse, mutect2, varscan2
- CDH22 | c.636C>A p.D212E | Missense Mutation (SNP) | VAF 28/274 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.41); catalogued as COSV64836498; called by muse, mutect2
- CDH23 | c.6539C>G p.T2180R | Missense Mutation (SNP) | VAF 66/404 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs781425553; called by muse, mutect2, varscan2
- CHRNA4 | c.314A>G p.Y105C | Missense Mutation (SNP) | VAF 29/244 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771191068; called by muse, mutect2, varscan2
- COL11A1 | c.2698C>G p.P900A | Missense Mutation (SNP) | VAF 84/986 reads (9%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); catalogued as COSV62190247; called by muse, mutect2
- COL7A1 | c.83G>A p.R28K | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as rs1334243008; called by muse, mutect2, varscan2
- DLG2 | c.2041C>G p.R681G | Missense Mutation (SNP) | VAF 43/408 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54681198; called by muse, mutect2, varscan2
- F13A1 | c.451C>A p.P151T | Missense Mutation (SNP) | VAF 62/541 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.7); catalogued as COSV53559272; called by muse, mutect2, varscan2
- FAM71B | c.1231C>G p.R411G | Missense Mutation (SNP) | VAF 59/491 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV57230515; called by muse, mutect2, varscan2
- FCGR1A | c.781G>C p.E261Q | Missense Mutation (SNP) | VAF 95/1222 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV64985795; called by muse, mutect2
- FCRL5 | c.2005C>G p.Q669E | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as rs1558129365, COSV100708994; called by muse, mutect2, varscan2
- FNBP4 | c.362A>G p.N121S | Missense Mutation (SNP) | VAF 30/280 reads (11%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as rs745468284; called by muse, mutect2
- FNDC8 | c.37G>C p.E13Q | Missense Mutation (SNP) | VAF 87/371 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.69); catalogued as COSV99338563; called by muse, mutect2, varscan2
- FOXB2 | c.584C>A p.P195Q | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV100942400; called by muse, mutect2, varscan2
- GK2 | c.625A>G p.N209D | Missense Mutation (SNP) | VAF 31/281 reads (11%) | SIFT tolerated (0.3); PolyPhen probably damaging (1); catalogued as rs770894261; called by muse, mutect2, varscan2
- HEPACAM2 | c.1094C>A p.S365Y (on ENST00000394468 / NM_001039372.4; = p.S353Y on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/176 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.556); catalogued as COSV59062533; called by muse, mutect2, varscan2
- HEPH | c.1178A>G p.Y393C (on ENST00000343002; = p.Y126C on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/158 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1343935757, COSV100294235; called by muse, mutect2, varscan2
- KCNC2 | c.1663C>A p.P555T | Missense Mutation (SNP) | VAF 37/214 reads (17%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.019); catalogued as COSV54366338; called by muse, mutect2, varscan2
- KCNH6 | c.2351C>T p.P784L | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.079); catalogued as COSV100121064; called by muse, mutect2
- KIF2B | c.1432C>A p.L478I | Missense Mutation (SNP) | VAF 18/145 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs991737337; called by muse, mutect2, varscan2
- LAMA2 | c.830C>A p.S277* | Nonsense Mutation (SNP) | VAF 34/582 reads (6%) | catalogued as CM1311875, COSV101370516; called by muse, mutect2
- LRP1 | c.10124G>T p.R3375L | Missense Mutation (SNP) | VAF 40/233 reads (17%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.962); catalogued as COSV54510324; called by muse, mutect2, varscan2
- LRP1B | c.83-1G>T p.X28_splice | Splice Site (SNP) | VAF 23/227 reads (10%) | catalogued as COSV67192593; called by muse, mutect2, varscan2
- LTBP2 | c.4262C>A p.A1421E | Missense Mutation (SNP) | VAF 64/498 reads (13%) | SIFT tolerated (0.77); PolyPhen benign (0.127); catalogued as COSV56211377; called by muse, mutect2, varscan2
- MDGA1 | c.1130C>T p.P377L | Missense Mutation (SNP) | VAF 57/439 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as rs757695690; called by muse, mutect2, varscan2
- MTREX | c.1695G>T p.L565F | Missense Mutation (SNP) | VAF 21/161 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV57929017; called by muse, mutect2, varscan2
- MUC16 | c.10014G>T p.K3338N | Missense Mutation (SNP) | VAF 47/279 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.882); catalogued as COSV67474114; called by muse, mutect2, varscan2
- NPAP1 | c.1196C>A p.P399H | Missense Mutation (SNP) | VAF 56/415 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as rs754053840; called by muse, mutect2, varscan2
- NTRK3 | c.510G>C p.W170C | Missense Mutation (SNP) | VAF 37/263 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58129838; called by muse, mutect2, varscan2
- NTS | c.403G>T p.G135* | Nonsense Mutation (SNP) | VAF 39/294 reads (13%) | catalogued as COSV55455713; called by muse, mutect2, varscan2
- OR2G3 | c.716G>T p.S239I | Missense Mutation (SNP) | VAF 22/193 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); catalogued as COSV60680781; called by muse, mutect2, varscan2
- PCDHB8 | c.1009C>G p.Q337E | Missense Mutation (SNP) | VAF 40/596 reads (7%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.006); catalogued as COSV50788769; called by muse, mutect2
- PEX11B | c.175C>G p.L59V | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as rs1553754023, COSV57161756; called by muse, mutect2
- PGA3 | c.103C>T p.R35C | Missense Mutation (SNP) | VAF 37/326 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs1299591409, COSV100337347; called by muse, mutect2, varscan2
- PLEKHA6 | c.2006G>T p.R669L | Missense Mutation (SNP) | VAF 21/173 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as COSV55340898; called by muse, mutect2, varscan2
- POM121C | c.883G>C p.E295Q (on ENST00000607367; = p.E53Q on NM_001099415.3) | Missense Mutation (SNP) | VAF 118/666 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.615); catalogued as COSV57548381; called by muse, mutect2, varscan2
- RIOK2 | c.1103G>T p.R368I | Missense Mutation (SNP) | VAF 32/251 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV51612634; called by muse, mutect2, varscan2
- RSPRY1 | c.825G>T p.L275F | Missense Mutation (SNP) | VAF 45/385 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.542); catalogued as COSV68028124; called by muse, mutect2, varscan2
- SLC12A3 | c.775G>T p.D259Y | Missense Mutation (SNP) | VAF 29/315 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM121286; called by muse, mutect2
- SLC6A15 | c.85G>T p.A29S | Missense Mutation (SNP) | VAF 60/480 reads (13%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV57021625; called by muse, mutect2, varscan2
- SLC8A1 | c.1131C>A p.N377K | Missense Mutation (SNP) | VAF 20/181 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as COSV60491960; called by muse, mutect2, varscan2
- SLC8A3 | c.935C>A p.S312Y | Missense Mutation (SNP) | VAF 64/426 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV63523166; called by muse, mutect2, varscan2
- SLCO4A1 | c.1878G>A p.G626= | Splice Region (SNP) | VAF 9/79 reads (11%) | catalogued as COSV53890967; called by muse, varscan2
- SYNE2 | c.11395G>A p.A3799T | Missense Mutation (SNP) | VAF 68/866 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as COSV59954593; called by muse, mutect2
- TAF1L | c.4826C>G p.T1609S | Missense Mutation (SNP) | VAF 34/292 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.53); catalogued as rs771730127; called by muse, mutect2, varscan2
- TMPRSS15 | c.2159del p.G720Dfs*2 | Frame Shift Del (DEL) | VAF 55/524 reads (10%) | catalogued as COSV99518476; called by mutect2, pindel, varscan2
- TMPRSS15 | c.637G>T p.G213C | Missense Mutation (SNP) | VAF 28/350 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs762102731; called by muse, mutect2
- TREML1 | c.779C>T p.P260L | Missense Mutation (SNP) | VAF 71/594 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV64191535; called by muse, mutect2, varscan2
- TRIM51 | c.1107C>A p.D369E | Missense Mutation (SNP) | VAF 56/856 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.182); catalogued as COSV55269579; called by muse, mutect2
- UGT3A2 | c.591C>A p.F197L | Missense Mutation (SNP) | VAF 58/486 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.302); catalogued as COSV56934067; called by muse, mutect2, varscan2
- ZNF532 | c.3550G>C p.E1184Q | Missense Mutation (SNP) | VAF 36/413 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV60174689; called by muse, mutect2
- ABCB5 | c.681G>T p.M227I | Missense Mutation (SNP) | VAF 32/195 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAMTS10 | c.1267C>A p.H423N | Missense Mutation (SNP) | VAF 40/257 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ADAMTS14 | c.2461_2463del p.S821del | In Frame Del (DEL) | VAF 16/118 reads (14%) | called by pindel, varscan2
- ADGRL3 | c.4454A>G p.H1485R (on ENST00000506720 / NM_001322402.2; = p.H1374R on NM_015236.6) | Missense Mutation (SNP) | VAF 53/704 reads (8%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.007); called by muse, mutect2
- ADGRV1 | c.8350G>T p.V2784L | Missense Mutation (SNP) | VAF 28/380 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2
- AGPAT3 | c.655del p.R219Gfs*10 | Frame Shift Del (DEL) | VAF 5/29 reads (17%) | called by mutect2, pindel
- AJM1 | c.1369C>A p.P457T | Missense Mutation (SNP) | VAF 25/240 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.098); called by muse, mutect2
- AKAP6 | c.1585G>T p.V529L | Missense Mutation (SNP) | VAF 28/341 reads (8%) | SIFT tolerated (0.91); PolyPhen benign (0); called by muse, mutect2
- AP4B1 | c.1690G>T p.V564L | Missense Mutation (SNP) | VAF 47/387 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ARMC4 | c.2005A>T p.I669F | Missense Mutation (SNP) | VAF 20/239 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.627); called by muse, mutect2
- ARMC4 | c.2003C>A p.A668E | Missense Mutation (SNP) | VAF 18/230 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.842); called by muse, mutect2
- ATOH7 | c.440C>A p.P147H | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ATP1A2 | c.1711G>A p.D571N | Missense Mutation (SNP) | VAF 52/491 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- ATP2C2 | c.768G>C p.R256S | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.096); called by muse, mutect2
- C9 | c.1331T>G p.L444R | Missense Mutation (SNP) | VAF 58/579 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2
- CD1E | c.267G>T p.E89D | Missense Mutation (SNP) | VAF 50/486 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2
- CENPC | c.1451A>T p.K484M | Missense Mutation (SNP) | VAF 9/191 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.079); called by muse, mutect2
- CERKL | c.995T>A p.V332D (on ENST00000339098 / NM_001030311.2; = p.V306D on NM_201548.5) | Missense Mutation (SNP) | VAF 48/562 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- CFH | c.8T>A p.L3H | Missense Mutation (SNP) | VAF 33/500 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- CLCA1 | c.1280A>T p.Q427L | Missense Mutation (SNP) | VAF 29/454 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.497); called by muse, mutect2
- CLCN1 | c.1800dup p.Y601Ifs*6 | Frame Shift Ins (INS) | VAF 85/615 reads (14%) | called by mutect2, pindel, varscan2
- CLEC5A | c.493G>T p.G165C | Missense Mutation (SNP) | VAF 44/474 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CNOT1 | c.1990C>T p.Q664* | Nonsense Mutation (SNP) | VAF 28/262 reads (11%) | called by muse, varscan2
- COL11A1 | c.17C>G p.S6C | Missense Mutation (SNP) | VAF 64/680 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.058); called by muse, mutect2
- CSF2RA | c.1133G>T p.W378L | Missense Mutation (SNP) | VAF 28/420 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); called by muse, mutect2
- CYP7B1 | c.666G>T p.K222N | Missense Mutation (SNP) | VAF 47/362 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DECR2 | c.104G>T p.G35V | Missense Mutation (SNP) | VAF 19/165 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DENND5B | c.1711A>G p.I571V | Missense Mutation (SNP) | VAF 39/316 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- DMD | c.758T>A p.M253K | Missense Mutation (SNP) | VAF 59/293 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- DNAH3 | c.2753C>G p.S918C | Missense Mutation (SNP) | VAF 25/595 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.621); called by muse, mutect2
- DNAH5 | c.10099C>T p.Q3367* | Nonsense Mutation (SNP) | VAF 227/1242 reads (18%) | called by muse, mutect2, varscan2
- EFL1 | c.1020G>C p.Q340H | Missense Mutation (SNP) | VAF 13/371 reads (4%) | SIFT tolerated (0.59); PolyPhen benign (0.033); called by muse, mutect2
- ELAC1 | c.475G>T p.D159Y | Missense Mutation (SNP) | VAF 46/514 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- ELOA2 | c.1352C>A p.P451Q | Missense Mutation (SNP) | VAF 77/680 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- EPB41L3 | c.1699G>A p.G567R | Missense Mutation (SNP) | VAF 22/204 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, varscan2
- EPPK1 | c.2140G>T p.E714* | Nonsense Mutation (SNP) | VAF 14/230 reads (6%) | called by muse, mutect2
- EXOC5 | c.2019A>C p.Q673H | Missense Mutation (SNP) | VAF 44/428 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- F2RL1 | c.358G>C p.A120P | Missense Mutation (SNP) | VAF 47/291 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM9A | c.22C>A p.R8S | Missense Mutation (SNP) | VAF 38/149 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.555); called by muse, mutect2, varscan2
- FCGBP | c.2671G>C p.V891L | Missense Mutation (SNP) | VAF 24/197 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- FKBP1C | c.322del p.E108Nfs*9 | Frame Shift Del (DEL) | VAF 30/304 reads (10%) | called by mutect2, pindel
- FLT4 | c.2168-8C>A | Splice Region (SNP) | VAF 5/43 reads (12%) | called by muse, mutect2
- GLB1L3 | c.629C>T p.P210L | Missense Mutation (SNP) | VAF 27/231 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.286); called by muse, mutect2, varscan2
- GOLGA8J | c.1669C>A p.P557T | Missense Mutation (SNP) | VAF 55/536 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- GPR119 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 7/42 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.916); called by muse, varscan2
- GRB7 | c.1580G>A p.C527Y | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- GRIN3A | c.2206C>A p.P736T | Missense Mutation (SNP) | VAF 49/364 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- GSG1L | c.247G>T p.G83C | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.454); called by muse, varscan2
- HOXB13 | c.316C>A p.L106M | Missense Mutation (SNP) | VAF 22/228 reads (10%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.985); called by muse, mutect2
- HSPB1 | c.157G>T p.G53C | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IFNA2 | c.159G>C p.L53F | Missense Mutation (SNP) | VAF 25/335 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- IGHV4-28 | c.280T>A p.S94T | Missense Mutation (SNP) | VAF 111/1028 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- IL13RA1 | c.1004G>T p.S335I | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- IL1R2 | c.119G>A p.R40K | Missense Mutation (SNP) | VAF 34/272 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.189); called by muse, varscan2
- IPO5 | c.2121G>A p.M707I | Missense Mutation (SNP) | VAF 18/398 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2
- ITGA5 | c.3058C>T p.L1020F | Missense Mutation (SNP) | VAF 18/225 reads (8%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); called by muse, mutect2
- ITIH3 | c.2620G>A p.E874K | Missense Mutation (SNP) | VAF 53/454 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ITPR3 | c.584A>G p.H195R | Missense Mutation (SNP) | VAF 24/310 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); called by muse, mutect2
- KANSL3 | c.14G>T p.G5V | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- KIAA1109 | c.1495A>T p.T499S | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT tolerated (0.62); PolyPhen benign (0.003); called by muse, varscan2
- L1TD1 | c.449A>T p.N150I | Missense Mutation (SNP) | VAF 41/297 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- LAMA1 | c.4005C>G p.I1335M | Missense Mutation (SNP) | VAF 52/734 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LMTK3 | c.307C>A p.L103I | Missense Mutation (SNP) | VAF 20/212 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2
- LMX1A | c.640T>A p.F214I | Missense Mutation (SNP) | VAF 22/193 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- LRIG2 | c.3143A>T p.H1048L | Missense Mutation (SNP) | VAF 56/545 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- LRRC53 | c.580G>C p.A194P | Missense Mutation (SNP) | VAF 56/485 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- MAGEB18 | c.295G>C p.A99P | Missense Mutation (SNP) | VAF 63/365 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- MCCC1 | c.2138A>T p.E713V | Missense Mutation (SNP) | VAF 101/862 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- MGAT5B | c.49del p.V17Sfs*3 | Frame Shift Del (DEL) | VAF 35/273 reads (13%) | called by mutect2, pindel, varscan2
- MTHFS | c.31C>T p.R11W | Missense Mutation (SNP) | VAF 9/211 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); called by muse, mutect2
- MUC17 | c.13426G>A p.D4476N | Missense Mutation (SNP) | VAF 36/336 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- MUTYH | c.1544G>T p.S515I | Missense Mutation (SNP) | VAF 30/348 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.034); called by muse, mutect2
- MYCBPAP | c.2287A>C p.M763L | Missense Mutation (SNP) | VAF 9/147 reads (6%) | SIFT tolerated (0.68); PolyPhen benign (0.001); called by muse, mutect2
- MYH4 | c.1058A>G p.Y353C | Missense Mutation (SNP) | VAF 34/275 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MYO5B | c.1669-1G>T p.X557_splice | Splice Site (SNP) | VAF 57/852 reads (7%) | called by muse, mutect2
- NEB | c.11656G>A p.G3886R | Missense Mutation (SNP) | VAF 23/284 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- NEUROG1 | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- NLRP2 | c.355G>T p.D119Y | Missense Mutation (SNP) | VAF 53/487 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- NRXN3 | c.1150G>T p.G384* (on ENST00000335750 / NM_001330195.2; = p.G11* on NM_004796.6) | Nonsense Mutation (SNP) | VAF 26/324 reads (8%) | called by muse, mutect2
- NT5DC4 | c.376C>A p.L126I | Missense Mutation (SNP) | VAF 27/337 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); called by muse, mutect2
- NTRK1 | c.2203G>T p.E735* | Nonsense Mutation (SNP) | VAF 17/173 reads (10%) | called by muse, mutect2
- OR11H2 | c.796C>A p.P266T (on ENST00000556246; = p.P277T on NM_001197287.1) | Missense Mutation (SNP) | VAF 97/877 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- OR5T3 | c.106C>T p.Q36* | Nonsense Mutation (SNP) | VAF 39/343 reads (11%) | called by muse, varscan2
- PCDHB6 | c.2137A>T p.R713W | Missense Mutation (SNP) | VAF 41/344 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PHC2 | c.734C>G p.P245R | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PHLPP1 | c.1711G>T p.V571L | Missense Mutation (SNP) | VAF 23/317 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); called by muse, mutect2
- PIP4K2C | c.370G>T p.V124L | Missense Mutation (SNP) | VAF 26/179 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.14); called by muse, varscan2
- PLCL2 | c.559G>T p.D187Y (on ENST00000615277 / NM_001144382.2; = p.D61Y on NM_015184.5) | Missense Mutation (SNP) | VAF 35/293 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- PLCXD3 | c.509T>A p.M170K | Missense Mutation (SNP) | VAF 65/744 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.046); called by muse, mutect2
- PROKR1 | c.706A>T p.I236F | Missense Mutation (SNP) | VAF 48/450 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- PRR23A | c.472G>T p.E158* | Nonsense Mutation (SNP) | VAF 26/298 reads (9%) | called by muse, mutect2
- PRR23A | c.471G>T p.E157D | Missense Mutation (SNP) | VAF 26/304 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.031); called by muse, mutect2
- RABGAP1L | c.1799A>T p.Q600L | Missense Mutation (SNP) | VAF 24/332 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RAD51AP2 | c.2173C>A p.H725N | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.018); called by muse, mutect2
- RBM12 | c.2153G>T p.G718V | Missense Mutation (SNP) | VAF 22/372 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- RBM12 | c.1141C>G p.Q381E | Missense Mutation (SNP) | VAF 61/631 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.845); called by muse, mutect2
- RTBDN | c.245C>A p.P82Q (on ENST00000393233 / NM_001270444.1; = p.P114Q on NM_031429.2) | Missense Mutation (SNP) | VAF 22/193 reads (11%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- RYR2 | c.6044G>T p.G2015V | Missense Mutation (SNP) | VAF 19/178 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- SALL1 | c.3368T>C p.L1123P | Missense Mutation (SNP) | VAF 26/316 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.076); called by muse, mutect2
- SCN3A | c.1339C>A p.Q447K | Missense Mutation (SNP) | VAF 55/588 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.04); called by muse, mutect2
- SCUBE1 | c.976G>C p.E326Q | Missense Mutation (SNP) | VAF 27/172 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SETD1A | c.4774G>A p.E1592K | Missense Mutation (SNP) | VAF 20/168 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SIDT2 | c.769G>T p.G257W | Missense Mutation (SNP) | VAF 33/284 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC44A5 | c.1841T>C p.F614S | Missense Mutation (SNP) | VAF 14/202 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); called by muse, mutect2
- SLC4A3 | c.1198G>T p.V400L | Missense Mutation (SNP) | VAF 29/263 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- SNRNP200 | c.3766G>C p.V1256L | Missense Mutation (SNP) | VAF 68/578 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- SP140L | c.533C>T p.P178L | Missense Mutation (SNP) | VAF 18/312 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.302); called by muse, mutect2
- SPOCK3 | c.608A>T p.D203V | Missense Mutation (SNP) | VAF 39/403 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- STAB2 | c.5698-1G>C p.X1900_splice | Splice Site (SNP) | VAF 19/90 reads (21%) | called by muse, mutect2, varscan2
- STOML2 | c.741del p.L248Wfs*18 | Frame Shift Del (DEL) | VAF 18/154 reads (12%) | called by mutect2, pindel, varscan2
- SYNE2 | c.7250A>T p.K2417I | Missense Mutation (SNP) | VAF 53/449 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- TANC2 | c.5291C>G p.P1764R | Missense Mutation (SNP) | VAF 41/327 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- TCERG1L | c.1135C>A p.L379I | Missense Mutation (SNP) | VAF 18/197 reads (9%) | SIFT tolerated (0.59); PolyPhen benign (0.023); called by muse, mutect2
- TENM2 | c.419G>C p.R140P | Missense Mutation (SNP) | VAF 75/812 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- TMOD1 | c.617G>T p.R206L | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2
- TMOD1 | c.618G>T p.R206= | Splice Region (SNP) | VAF 14/156 reads (9%) | called by muse, mutect2
- TRAPPC9 | c.3040G>T p.A1014S | Missense Mutation (SNP) | VAF 40/418 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.333); called by muse, mutect2
- TRPM5 | c.1542C>A p.S514R | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- TYRP1 | c.73C>A p.Q25K | Missense Mutation (SNP) | VAF 28/257 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- UHRF1BP1L | c.1163G>T p.W388L | Missense Mutation (SNP) | VAF 35/307 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UNC80 | c.2131C>A p.P711T | Missense Mutation (SNP) | VAF 34/342 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); called by muse, mutect2
- WASHC5 | c.2119G>T p.E707* | Nonsense Mutation (SNP) | VAF 69/604 reads (11%) | called by muse, mutect2, varscan2
- XIRP2 | c.7652A>G p.D2551G (on ENST00000628543; = p.D2726G on NM_152381.6) | Missense Mutation (SNP) | VAF 19/211 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2
- ZFY | c.1896G>C p.L632F | Missense Mutation (SNP) | VAF 105/469 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- ZNF208 | c.1654C>A p.P552T | Missense Mutation (SNP) | VAF 32/308 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- ZNF331 | c.1267G>T p.G423C | Missense Mutation (SNP) | VAF 34/446 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.59); called by muse, mutect2
- ZNF565 | c.215G>T p.R72M (on ENST00000355114; = p.R32M on NM_152477.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 51/402 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- ZNF644 | c.1435G>T p.E479* | Nonsense Mutation (SNP) | VAF 42/908 reads (5%) | called by muse, mutect2
- ZNF701 | c.745A>T p.R249W (on ENST00000301093; = p.R183W on NM_018260.3) | Missense Mutation (SNP) | VAF 33/312 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZSCAN25 | c.1258G>T p.V420L | Missense Mutation (SNP) | VAF 11/291 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.438); called by muse, mutect2
- ALLC | c.724C>A p.R242= | Silent (SNP) | VAF 19/284 reads (7%) | called by muse, mutect2
- ARPP21 | c.1602C>A p.V534= | Silent (SNP) | VAF 21/131 reads (16%) | catalogued as COSV51802826; called by muse, mutect2, varscan2
- BCHE | c.234C>A p.T78= | Silent (SNP) | VAF 16/149 reads (11%) | called by muse, mutect2, varscan2
- BIRC6 | c.6816G>T p.L2272= | Silent (SNP) | VAF 36/370 reads (10%) | called by muse, mutect2
- BMP6 | c.795G>T p.G265= | Silent (SNP) | VAF 31/347 reads (9%) | catalogued as COSV51660357; called by muse, mutect2
- BOD1L1 | c.2952A>T p.T984= | Silent (SNP) | VAF 32/206 reads (16%) | called by muse, mutect2, varscan2
- C4orf54 | c.1365C>A p.P455= | Silent (SNP) | VAF 5/35 reads (14%) | called by muse, mutect2, varscan2
- CHRM3 | c.1674G>C p.L558= | Silent (SNP) | VAF 27/441 reads (6%) | called by muse, mutect2
- CLEC4F | c.540C>A p.I180= | Silent (SNP) | VAF 49/375 reads (13%) | catalogued as COSV55478557; called by muse, mutect2, varscan2
- CREB5 | c.207C>T p.C69= (on ENST00000357727 / NM_182898.4; = p.C62= on NM_004904.3) | Silent (SNP) | VAF 24/338 reads (7%) | catalogued as rs1396126152; called by muse, mutect2
- CSMD1 | c.8301G>T p.T2767= (on ENST00000520002; = p.T2766= on NM_033225.6) | Silent (SNP) | VAF 32/358 reads (9%) | catalogued as rs765938760, COSV59315997, COSV59328648, COSV59361465; called by muse, mutect2
- CYLC2 | c.126G>T p.R42= | Silent (SNP) | VAF 26/421 reads (6%) | catalogued as COSV66337219; called by muse, mutect2
- DCDC1 | c.5157C>T p.S1719= (on ENST00000597505 / NM_001367979.1; = p.S826= on NM_020869.3) | Silent (SNP) | VAF 42/446 reads (9%) | called by muse, mutect2
- DIS3 | c.102C>T p.P34= | Silent (SNP) | VAF 6/136 reads (4%) | catalogued as rs1388000752; called by muse, mutect2
- DSCAML1 | c.2409C>A p.R803= (on ENST00000321322; = p.R743= on NM_020693.4) | Silent (SNP) | VAF 23/214 reads (11%) | called by muse, mutect2, varscan2
- EIF4H | c.261A>G p.V87= | Silent (SNP) | VAF 57/308 reads (19%) | called by muse, mutect2, varscan2
- FAM117B | c.1005C>T p.T335= | Silent (SNP) | VAF 40/416 reads (10%) | called by muse, mutect2
- FAT2 | c.12390A>G p.T4130= | Silent (SNP) | VAF 25/190 reads (13%) | called by muse, mutect2, varscan2
- FAT3 | c.13308C>A p.P4436= | Silent (SNP) | VAF 32/503 reads (6%) | catalogued as COSV53127882; called by muse, mutect2
- FNDC1 | c.2425C>A p.R809= | Silent (SNP) | VAF 17/145 reads (12%) | catalogued as rs538507376, COSV51931507; called by muse, mutect2, varscan2
- FOXC2 | c.849G>T p.P283= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as rs1458484818, COSV100234234; called by muse, mutect2, varscan2
- FSIP2 | c.7644G>A p.G2548= | Silent (SNP) | VAF 22/296 reads (7%) | called by muse, mutect2
- FZD1 | c.1659C>T p.A553= | Silent (SNP) | VAF 55/352 reads (16%) | called by muse, mutect2, varscan2
- GRIN3A | c.1093C>T p.L365= | Silent (SNP) | VAF 18/195 reads (9%) | called by muse, mutect2
- GYPC | c.153C>A p.T51= | Silent (SNP) | VAF 44/640 reads (7%) | called by muse, mutect2
- IMPACT | c.630G>A p.K210= | Silent (SNP) | VAF 20/252 reads (8%) | catalogued as COSV52422566; called by muse, mutect2
- MMP16 | c.264G>T p.V88= | Silent (SNP) | VAF 48/421 reads (11%) | called by muse, mutect2, varscan2
- MTRNR2L7 | c.6C>A p.A2= | Silent (SNP) | VAF 22/136 reads (16%) | called by muse, mutect2, varscan2
- OR2A25 | c.663A>G p.L221= | Silent (SNP) | VAF 53/278 reads (19%) | called by muse, mutect2, varscan2
- OR2B3 | c.297C>A p.A99= | Silent (SNP) | VAF 31/303 reads (10%) | called by muse, mutect2, varscan2
- OR2T3 | c.498C>A p.P166= | Silent (SNP) | VAF 18/323 reads (6%) | catalogued as COSV100613479; called by muse, mutect2
- OR4C13 | c.342T>A p.T114= | Silent (SNP) | VAF 36/279 reads (13%) | called by muse, mutect2, varscan2
- OR51B6 | c.306C>A p.I102= | Silent (SNP) | VAF 26/238 reads (11%) | catalogued as COSV66512399; called by muse, mutect2, varscan2
- OR51E1 | c.597C>G p.V199= | Silent (SNP) | VAF 38/311 reads (12%) | called by muse, mutect2, varscan2
- OR5T3 | c.105G>T p.L35= | Silent (SNP) | VAF 40/346 reads (12%) | called by muse, varscan2
- OR8D4 | c.711G>T p.A237= | Silent (SNP) | VAF 31/259 reads (12%) | catalogued as COSV58431321; called by muse, mutect2, varscan2
- PAK5 | c.1368G>T p.G456= | Silent (SNP) | VAF 46/424 reads (11%) | called by muse, mutect2, varscan2
- PCDHGA2 | c.1971T>A p.T657= | Silent (SNP) | VAF 43/389 reads (11%) | called by muse, mutect2, varscan2
- PDZD4 | c.1050G>C p.T350= | Silent (SNP) | VAF 11/52 reads (21%) | called by muse, mutect2, varscan2
- PSEN2 | c.540G>C p.L180= | Silent (SNP) | VAF 78/942 reads (8%) | called by muse, mutect2
- PXDN | c.2319T>C p.N773= | Silent (SNP) | VAF 38/523 reads (7%) | called by muse, mutect2
- RBM12 | c.2154G>T p.G718= | Silent (SNP) | VAF 22/374 reads (6%) | called by muse, mutect2
- RYR2 | c.5781C>A p.A1927= | Silent (SNP) | VAF 32/370 reads (9%) | called by muse, mutect2
- SETD4 | c.843C>T p.F281= | Silent (SNP) | VAF 82/891 reads (9%) | catalogued as rs985314762; called by muse, mutect2
- SIX4 | c.252A>G p.V84= | Silent (SNP) | VAF 11/82 reads (13%) | called by muse, mutect2
- SLC30A10 | c.78G>T p.L26= | Silent (SNP) | VAF 31/251 reads (12%) | called by muse, mutect2, varscan2
- STMN3 | c.51G>T p.V17= | Silent (SNP) | VAF 18/150 reads (12%) | called by muse, varscan2
- SULT2A1 | c.303C>A p.P101= | Silent (SNP) | VAF 30/232 reads (13%) | called by muse, varscan2
- SYT10 | c.576C>A p.G192= | Silent (SNP) | VAF 42/328 reads (13%) | called by muse, mutect2, varscan2
- TCHH | c.2416C>A p.R806= | Silent (SNP) | VAF 24/184 reads (13%) | called by muse, mutect2, varscan2
- TNFSF18 | c.327G>T p.L109= | Silent (SNP) | VAF 27/198 reads (14%) | catalogued as COSV53442190; called by muse, mutect2, varscan2
- XRRA1 | c.87G>A p.P29= | Silent (SNP) | VAF 39/259 reads (15%) | catalogued as rs374959795; called by muse, mutect2, varscan2
- ZBP1 | c.1170G>A p.S390= | Silent (SNP) | VAF 20/283 reads (7%) | catalogued as rs576667622; called by muse, mutect2
- ZFYVE9 | c.3837C>T p.V1279= | Silent (SNP) | VAF 41/471 reads (9%) | catalogued as rs373689197; called by muse, mutect2
- ZNF574 | c.1095G>A p.L365= | Silent (SNP) | VAF 25/209 reads (12%) | catalogued as rs375916068; called by muse, mutect2, varscan2
- ZNF845 | c.579G>T p.G193= | Silent (SNP) | VAF 40/386 reads (10%) | called by muse, mutect2, varscan2
- ADH5P5 | chr5:23979963 G>T | 5'Flank (SNP) | VAF 28/222 reads (13%) | called by muse, mutect2, varscan2
- CCL4L2 | c.192-18G>A | Intron (SNP) | VAF 36/504 reads (7%) | called by muse, mutect2
- COL27A1 | c.2368-2018C>A | Intron (SNP) | VAF 23/163 reads (14%) | called by muse, mutect2, varscan2
- CPLX2 | c.-9G>T | 5'UTR (SNP) | VAF 22/236 reads (9%) | catalogued as COSV64002005; called by muse, mutect2
- CPNE6 | c.1113+17G>A | Intron (SNP) | VAF 39/319 reads (12%) | called by muse, mutect2, varscan2
- DST | c.4296+3994G>T | Intron (SNP) | VAF 47/332 reads (14%) | called by muse, mutect2, varscan2
- EGFL8 | c.-29+10G>T | Intron (SNP) | VAF 24/189 reads (13%) | called by muse, mutect2, varscan2
- FOXP2 | chr7:114086556 C>G | 5'Flank (SNP) | VAF 20/153 reads (13%) | called by muse, mutect2, varscan2
- HERC2P3 | n.769G>T | RNA (SNP) | VAF 63/920 reads (7%) | called by muse, mutect2
- HSP90AB3P | n.542G>A | RNA (SNP) | VAF 62/471 reads (13%) | called by muse, mutect2, varscan2
- MCRIP1 | c.-48-1408C>T | Intron (SNP) | VAF 34/207 reads (16%) | called by muse, mutect2, varscan2
- MIR520B | n.47C>G | RNA (SNP) | VAF 18/250 reads (7%) | called by muse, mutect2
- MYCT1 | c.*528A>T | 3'UTR (SNP) | VAF 14/137 reads (10%) | called by muse, mutect2, varscan2
- NOC2LP2 | n.168G>T | RNA (SNP) | VAF 17/170 reads (10%) | called by muse, mutect2, varscan2
- PCNP | c.-20G>T | 5'UTR (SNP) | VAF 8/61 reads (13%) | called by muse, mutect2, varscan2
- PDCD6 | c.-38C>A | 5'UTR (SNP) | VAF 57/187 reads (30%) | catalogued as rs573443710; called by muse, mutect2, varscan2
- PGC | c.*27C>G | 3'UTR (SNP) | VAF 38/394 reads (10%) | called by muse, mutect2
- PRICKLE4 | c.668-12G>T | Intron (SNP) | VAF 28/214 reads (13%) | called by muse, mutect2, varscan2
- SAMSN1 | c.-19G>A | 5'UTR (SNP) | VAF 33/298 reads (11%) | catalogued as rs763212013; called by muse, mutect2
- SETDB2 | c.1612+38G>T | Intron (SNP) | VAF 33/294 reads (11%) | called by muse, mutect2, varscan2
- SLC12A1 | c.628+404G>A | Intron (SNP) | VAF 8/148 reads (5%) | catalogued as rs1389805899; called by muse, mutect2
- SNORD114-25 | n.40C>G | RNA (SNP) | VAF 18/180 reads (10%) | called by muse, mutect2, varscan2
- TBX15 | c.1025-5407C>A | Intron (SNP) | VAF 36/357 reads (10%) | catalogued as rs953305025; called by muse, mutect2, varscan2
- TLCD3B | chr16:30035457 C>T | 5'Flank (SNP) | VAF 15/159 reads (9%) | called by muse, mutect2
- TM7SF2 | c.249+49G>T | Intron (SNP) | VAF 17/109 reads (16%) | called by muse, mutect2, varscan2
- VWA5B2 | c.-18G>T | 5'UTR (SNP) | VAF 9/53 reads (17%) | called by muse, mutect2, varscan2
- WWP2 | c.1683-817A>G | Intron (SNP) | VAF 14/158 reads (9%) | called by muse, mutect2
- ZWINT | c.*115G>T | 3'UTR (SNP) | VAF 69/615 reads (11%) | called by muse, mutect2, varscan2
